CCDI case PBBRIH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/50e32afa-83d4-4471-9de6-860e0ccfeaa7

Demographics
Sex at birth: female.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.6 years (2,418 days).

Biospecimens (4 samples)
- Sample 0DEYDN: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DEYDW, 0DF0BW (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DEYEF: Tissue type: Tumor; Specimen type: Solid Tissue.
